Somatic mutation profile of tumor specimen TCGA-39-5030-01A (aliquot TCGA-39-5030-01A-01D-1441-08) from TCGA case TCGA-39-5030, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.8 years (29,893 days).
Specimen TCGA-39-5030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77e5d44d-586f-4566-943c-399fe47b8071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5030-11A (Solid Tissue Normal), aliquot TCGA-39-5030-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52c80414-9fb4-4b96-b699-b72c64d8110f

The open-access MAF lists 189 somatic variants for this specimen: 145 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 41, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 2, Splice Region 2, 5'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKLR | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315362, CM910300, COSV61360632; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59383967; called by muse, mutect2, varscan2
- AARD | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV65599623; called by muse, mutect2, varscan2
- AC004922.1 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.762); catalogued as COSV53555872; called by muse, mutect2
- ACHE | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1563036152, COSV53815738; called by muse, mutect2, varscan2
- ADGRL3 | c.3064G>T p.A1022S (on ENST00000506720 / NM_001322402.2; = p.A954S on NM_015236.6) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.377); catalogued as COSV72229857; called by muse, varscan2
- ADIPOR2 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV63945437, COSV63945687; called by muse, mutect2, varscan2
- ANAPC5 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs115934510, COSV55841788; called by muse, mutect2
- ANKLE2 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV61708206; called by muse, mutect2
- ARHGAP17 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as COSV51505447; called by muse, mutect2
- ARHGAP36 | c.1284G>T p.V428= | Splice Region (SNP) | VAF 9/115 reads (8%) | catalogued as COSV52264834; called by muse, mutect2
- ARHGAP44 | c.1868G>C p.G623A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV52390482, COSV52404681; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV63437266; called by muse, mutect2, varscan2
- ATP2B2 | c.1429G>C p.E477Q (on ENST00000352432; = p.E443Q on NM_001683.5) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59491491; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1150G>A p.V384I (on ENST00000272238 / NM_001039362.2; = p.V338I on NM_144583.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55349669; called by muse, mutect2, varscan2
- ATXN3L | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as rs1252801787, COSV101019398, COSV66075342; called by muse, mutect2
- B3GALT1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59908227; called by muse, mutect2
- BAZ2B | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV58597002; called by muse, mutect2
- BCL9 | c.3629G>T p.S1210I | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV52341946; called by muse, mutect2
- BRPF1 | c.3362C>A p.P1121H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57351632; called by muse, mutect2
- CABLES1 | c.848G>A p.R283Q (on ENST00000256925 / NM_001100619.2; = p.R18Q on NM_138375.2) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1230642741, COSV56931290; called by muse, mutect2
- CACNA1I | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60802892; called by muse, mutect2, varscan2
- CDC42BPA | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV62004854; called by muse, mutect2
- CDCP1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104212; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4759C>G p.P1587A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62572724; called by muse, mutect2
- CEP135 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs763361090, COSV57258605; called by muse, mutect2, varscan2
- CLDN3 | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67777058; called by muse, mutect2
- COL4A4 | c.2968+2T>A p.X990_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV61630275; called by muse, mutect2, varscan2
- COPA | c.3548A>G p.E1183G | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1365822478, COSV54099332; called by muse, mutect2, varscan2
- CRYBG1 | c.4830G>A p.M1610I | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV64811148; called by muse, mutect2
- CTNNA1 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.131); catalogued as rs1204441821, COSV57070699; called by muse, mutect2, varscan2
- CUL4B | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.65); catalogued as COSV60685520; called by muse, mutect2, varscan2
- CUL5 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV67608358; called by muse, mutect2, varscan2
- CUL9 | c.7028G>A p.R2343Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs763538988, COSV52726308; called by muse, mutect2, varscan2
- CYP4V2 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as COSV66505247; called by muse, mutect2, varscan2
- D2HGDH | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58319416; called by muse, mutect2, varscan2
- DCAF8L1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV71595167; called by muse, mutect2
- DDB1 | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.349); catalogued as rs1211666818, COSV57101492; called by muse, mutect2, varscan2
- DDX39A | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54390717; called by muse, mutect2
- DLGAP2 | c.2429G>A p.S810N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV70095715; called by muse, mutect2, varscan2
- DNAH5 | c.5191C>T p.Q1731* | Nonsense Mutation (SNP) | VAF 35/203 reads (17%) | catalogued as COSV54210179; called by muse, mutect2
- DSP | c.7754C>G p.S2585C | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV65791708; called by muse, mutect2, varscan2
- EFEMP2 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV57259411; called by muse, mutect2, varscan2
- EIF1B | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51762291; called by muse, mutect2, varscan2
- EIF3F | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV59141457, COSV59142013; called by muse, mutect2
- EMD | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as CM983737, COSV63962044, COSV63962434; called by muse, mutect2
- EMD | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV63962051; called by muse, mutect2, varscan2
- ETF1 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV100620781, COSV61930610; called by muse, mutect2
- EYA3 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779202966, COSV65815778; called by muse, mutect2
- FAM111B | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs556804835, COSV59111349; called by muse, mutect2
- FAM227B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV54807112; called by muse, mutect2
- FAM47C | c.1352G>C p.R451P | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100792254, COSV63724552, COSV63728416; called by muse, mutect2, varscan2
- FAT4 | c.5444G>T p.R1815L | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58675150, COSV58684354; called by muse, mutect2, varscan2
- FBXO4 | c.295T>C p.W99R | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55851515; called by muse, mutect2
- FGD1 | c.2065C>A p.L689M | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV64308239; called by muse, mutect2
- FOXC2 | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV57443855; called by muse, mutect2
- FTCD | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV52423914, COSV99385512; called by muse, mutect2, varscan2
- GALR1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1173376603, COSV55316201; called by muse, mutect2, varscan2
- GJA1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as CM092832, COSV56997306; called by muse, mutect2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs754199513; called by mutect2, varscan2
- HDX | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52973917; called by muse, mutect2
- ILKAP | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54517602; called by muse, mutect2
- INCENP | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV53913910, COSV53921130; called by muse, mutect2, varscan2
- IQCJ | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); catalogued as COSV101188157, COSV67331076; called by muse, mutect2
- IRS1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs753900721, COSV59334352; called by muse, mutect2, varscan2
- ITGA7 | c.3484C>A p.L1162M (on ENST00000555728; = p.L1118M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV57692804; called by muse, mutect2
- KCTD13 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs763903243, COSV58159480; called by muse, mutect2, varscan2
- KDM2B | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV65638723; called by muse, mutect2
- KRIT1 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60667180; called by muse, mutect2, varscan2
- KRT12 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52430208, COSV52430570; called by muse, mutect2
- LONP1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV62260856; called by muse, mutect2
- LRP4 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.099); catalogued as COSV66134564; called by muse, mutect2
- MAGED1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.25); catalogued as rs1569556057, COSV58514719; called by muse, mutect2, varscan2
- MED7 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53849808; called by muse, mutect2
- MKI67 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766987700, COSV64073124; called by muse, mutect2
- MUC17 | c.11867C>A p.A3956E | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV60282476; called by muse, mutect2, varscan2
- MYH11 | c.4656G>T p.E1552D | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV55545885; called by muse, mutect2
- NLK | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 11/160 reads (7%) | catalogued as COSV69407889; called by muse, mutect2
- NSD3 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV57617630; called by muse, mutect2, varscan2
- OCRL | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV63980399, COSV63980885; called by muse, mutect2, varscan2
- OPRK1 | c.612C>T p.D204= | Splice Region (SNP) | VAF 11/65 reads (17%) | catalogued as rs200735223, COSV55568962; called by muse, mutect2, varscan2
- OR13C4 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1231005102, COSV52926000; called by muse, mutect2
- OR2B11 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509578; called by muse, mutect2, varscan2
- OR52I2 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs926603084, COSV57044042; called by muse, mutect2
- PADI1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs781482161, COSV64937899; called by muse, mutect2
- PAPOLA | c.1571A>C p.D524A | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV53479694; called by muse, mutect2
- PCDHB2 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.8); catalogued as rs782784687, COSV52030220, COSV52033669; called by muse, mutect2, varscan2
- PCSK5 | c.4784G>A p.R1595H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs762598202, COSV101377740, COSV70448074; called by muse, mutect2, varscan2
- PER1 | c.2207C>A p.P736H | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57917795; called by muse, mutect2, varscan2
- PI4K2B | c.881T>A p.V294D | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53510591; called by muse, mutect2
- POLR2E | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.15); catalogued as COSV53123500; called by muse, mutect2
- PRDM15 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54149997; called by muse, mutect2
- PRKCQ | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54107805; called by muse, mutect2
- PRKDC | c.7255G>T p.D2419Y | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV58046359; called by muse, mutect2
- PRPF40A | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV62956987; called by muse, mutect2
- PRPSAP1 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61210645; called by muse, mutect2, varscan2
- PTAFR | c.99T>A p.N33K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536202; called by muse, mutect2, varscan2
- PTPRH | c.1872G>T p.R624S | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV54743469; called by muse, mutect2, varscan2
- PUF60 | c.1467G>C p.K489N (on ENST00000526683 / NM_001362896.2; = p.K472N on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV57583444, COSV57589562; called by muse, mutect2
- PYHIN1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs759449990, COSV63721739, COSV63723054; called by muse, mutect2, varscan2
- RABGAP1L | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52281914; called by muse, varscan2
- RFTN2 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV54386563; called by muse, mutect2
- RNF152 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as COSV57184343; called by muse, mutect2, varscan2
- RYR2 | c.14360A>T p.N4787I | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63669870; called by muse, mutect2
- SDCCAG8 | c.857G>C p.C286S | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59405907; called by muse, mutect2, varscan2
- SDHAF2 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.498); catalogued as COSV57098827; called by muse, mutect2
- SLC15A1 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV64730368; called by muse, mutect2, varscan2
- SLC30A2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs148861822; called by mutect2, varscan2
- SLC35D3 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV59377526, COSV59377780; called by mutect2, varscan2
- SLC39A1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1212651673, COSV57841423; called by muse, mutect2
- SMAP1 | c.1195G>A p.V399M (on ENST00000370455 / NM_001044305.3; = p.V372M on NM_021940.5) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1260077949, COSV57636356; called by muse, mutect2
- SMYD2 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65290487; called by muse, mutect2
- STK25 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV50869624; called by muse, mutect2
- STRADB | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99524288; called by muse, mutect2
- SUV39H2 | c.687C>A p.C229* (on ENST00000354919 / NM_001193424.2; = p.C169* on NM_024670.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV57953087; called by muse, mutect2
- SYNCRIP | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV62287005, COSV99051168; called by muse, mutect2, varscan2
- SYNJ2 | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62895970; called by muse, mutect2
- SYT11 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64173801; called by muse, mutect2
- TGFBRAP1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781418446, COSV51510476; called by mutect2, varscan2
- TMCC3 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV54152770; called by muse, varscan2
- TMEM161B | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56929721; called by muse, mutect2
- TNFAIP3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as rs1405321250, COSV52797285, COSV52798105; called by muse, mutect2
- TRIM56 | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60157610; called by muse, mutect2, varscan2
- TTC19 | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV55422201; called by muse, mutect2
- USP42 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs747842497, COSV60358377; called by mutect2, varscan2
- VANGL1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV59619718; called by muse, mutect2
- VAV1 | c.1173G>C p.E391D | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58380110; called by muse, mutect2
- VAV2 | c.2314C>T p.R772C (on ENST00000371850 / NM_001134398.2; = p.R762C on NM_003371.4) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1174972227, COSV64080558; called by muse, mutect2
- WDR70 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54268892; called by muse, mutect2
- WDR91 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV60368903; called by muse, mutect2
- WFIKKN2 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60958114; called by muse, mutect2, varscan2
- WWC1 | c.2216T>G p.L739R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54647107; called by muse, mutect2
- XIAP | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as COSV63021834; called by muse, mutect2, varscan2
- ZCCHC14 | c.2795-1G>T p.X932_splice (on ENST00000268616; = p.X1069_splice on NM_015144.3) | Splice Site (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99233444; called by muse, mutect2
- ZDBF2 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV65621831, COSV65622861; called by muse, mutect2, varscan2
- ZNF16 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145120548; called by muse, mutect2, varscan2
- ZNF189 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.214); catalogued as COSV52274556; called by muse, mutect2
- ZNF189 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.282); catalogued as COSV52274568; called by muse, mutect2
- ZNF512B | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as rs763691830, COSV53866916; called by muse, mutect2, varscan2
- ZNF614 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1271607297, COSV54545166; called by muse, mutect2
- ZSCAN22 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs201399248, COSV61638774; called by muse, mutect2
- CXCR3 | c.531del p.L178Sfs*119 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- LTF | c.359del p.G120Afs*6 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- SEC14L5 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- TIMP3 | c.602del p.P201Rfs*26 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- AC008397.2 | c.1098A>C p.P366= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV99441200; called by mutect2, varscan2
- ARV1 | c.639A>G p.V213= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV59617227; called by muse, mutect2
- ASCC3 | c.624C>T p.C208= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as rs1055390083, COSV61226537; called by muse, mutect2
- CDCP1 | c.1878C>T p.L626= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV56104201; called by muse, mutect2
- CHRNA6 | c.441C>A p.T147= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV52378774; called by muse, mutect2
- COL6A6 | c.306C>T p.G102= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs768634748, COSV62019781, COSV62022133; called by muse, mutect2, varscan2
- CYP4F11 | c.585C>T p.I195= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV56125975; called by muse, mutect2
- DHX8 | c.939G>C p.V313= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV52251542; called by muse, mutect2
- EEF1AKNMT | c.975G>C p.A325= (on ENST00000361735 / NM_015935.5; = p.A239= on NM_014955.3) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62282637; called by mutect2, varscan2
- EFNB1 | c.738C>T p.A246= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs773137160, COSV52661216; called by muse, varscan2
- FAM43A | c.345G>A p.A115= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV61672851; called by muse, mutect2, varscan2
- FCHSD1 | c.249C>T p.F83= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs772799960, COSV53349272; called by muse, mutect2, varscan2
- FTCD | c.6C>T p.S2= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV52423568; called by muse, mutect2, varscan2
- HSD17B10 | c.366C>T p.L122= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs797045616, COSV51447625, COSV51447814; ClinVar: uncertain significance; called by muse, mutect2
- HSPB1 | c.612C>T p.A204= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV50349078; called by muse, mutect2
- IGDCC4 | c.2298C>T p.I766= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV61535785; called by muse, mutect2
- IMPG2 | c.3342C>A p.V1114= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as rs1200677404, COSV51974870; called by muse, mutect2
- INPP4A | c.636C>T p.Y212= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs576701743, COSV50786321, COSV50827428; called by mutect2, varscan2
- KPNA3 | c.1092A>G p.V364= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV55503696; called by muse, mutect2
- LGSN | c.60T>C p.T20= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV65726445; called by muse, mutect2
- MTSS1 | c.2115C>A p.A705= | Silent (SNP) | VAF 37/578 reads (6%) | catalogued as COSV52674478; called by muse, mutect2
- MUC16 | c.21624C>A p.A7208= | Silent (SNP) | VAF 21/221 reads (10%) | catalogued as COSV67452206; called by muse, mutect2
- NEB | c.14373C>T p.I4791= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs113068669, COSV50845681; ClinVar: likely benign; called by muse, mutect2
- PDSS2 | c.219G>A p.L73= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as COSV64646713; called by muse, mutect2
- PIP5K1B | c.1134T>C p.H378= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as COSV55243095; called by muse, mutect2
- PRDM16 | c.333C>T p.G111= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1306832291, COSV54582093; called by muse, mutect2
- PSAPL1 | c.1014C>T p.I338= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV59842553; called by muse, mutect2, varscan2
- QTRT2 | c.1102C>T p.L368= | Silent (SNP) | VAF 14/308 reads (5%) | catalogued as COSV55559116; called by muse, mutect2
- RASGRF1 | c.747G>A p.L249= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV69177258; called by muse, mutect2, varscan2
- RCN1 | c.312G>C p.L104= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV50014362; called by muse, mutect2
- RXFP4 | c.982C>A p.R328= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV58142215, COSV58147753; called by muse, mutect2, varscan2
- SLC25A17 | c.474C>T p.R158= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs962467103, COSV54350696; called by muse, mutect2
- SLC44A4 | c.1698C>T p.Y566= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as rs145759335; called by muse, mutect2
- SPG11 | c.2058C>G p.L686= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV55991943; called by muse, mutect2
- ST6GAL2 | c.465G>A p.E155= | Silent (SNP) | VAF 45/299 reads (15%) | catalogued as COSV64526700; called by muse, mutect2, varscan2
- SYTL5 | c.229C>A p.R77= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV52899105; called by muse, mutect2, varscan2
- TLE5 | c.54C>G p.L18= | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as COSV55591833; called by muse, mutect2
- TMEFF2 | c.150G>A p.T50= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV55829376; called by muse, mutect2
- UBR5 | c.7735T>C p.L2579= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV55282117; called by muse, mutect2
- ZFHX4 | c.2229C>A p.A743= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV50593505; called by muse, mutect2, varscan2
- ZNF592 | c.1284G>T p.V428= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV55435517; called by muse, mutect2
- DDHD1 | chr14:53152847 G>A | 5'Flank (SNP) | VAF 7/47 reads (15%) | catalogued as rs1331865431, COSV60357800; called by muse, mutect2, varscan2
- DLL3 | c.*245C>T | 3'UTR (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99218743; called by muse, mutect2
- Y_RNA | chr14:50083742 C>G | 5'Flank (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
